TCGA case TCGA-AP-A0LL — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d17668c4-5d66-4e16-8b70-b54616581aae

Demographics
Sex at birth: female; Race: white; Age at index: 56 years; Vital status: Alive.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 56.7 years (20,700 days); Year of diagnosis: 2004; Method of diagnosis: Biopsy; FIGO stage: Stage IA; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,554 days (7.0 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 8.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 29.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 8.
   Treatment given: Treatment type: Brachytherapy, NOS; Treatment intent type: Adjuvant; Days to treatment start: 79 days; Days to treatment end: 100 days; Treatment dose: 2,100 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Megestrol Acetate; Initial disease status: Recurrent Disease; Days to treatment start: 829 days (2.3 years); Days to treatment end: 1,133 days (3.1 years); Number of cycles: 7; Treatment dose: 24,640 mg; Prescribed dose: 160; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Recurrent Disease; Days to treatment start: 829 days (2.3 years); Days to treatment end: 1,133 days (3.1 years); Number of cycles: 7; Treatment dose: 5,880 mg; Prescribed dose: 40; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 58.8 years (21,490 days); Days to diagnosis: 790 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Surgery, NOS; Residual disease: R0.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 790 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 790 days (2.2 years).
- Days to follow up: 2,141 days (5.9 years); Disease response: With Tumor.
- Days to follow up: 2,554 days (7.0 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 161 cm; BMI: 27.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AP-A0LL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-AP-A0LL-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AP-A0LL-01A-01-BSA: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AP-A0LL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AP-A0LL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form 1: History tamoxifen use: Never Used; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event surgery: Yes; New tumor event surgery days to met: 792; New tumor event procedure: Other Method, Specify Below; New tumor event procedure other: Locoregional; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Complete Response.
- Follow-up form 2: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 2; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Megace; Therapy regimen: Recurrence.
- Radiation treatment: Radiation type other: Intravaginal brachytherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,554 days; disease-specific survival: no event (censored), 2,554 days; disease-free interval: event (new tumor event after initially disease-free), 790 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 790 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AP-A0LL-01A-12D-A102-01): tumor purity 0.94, ploidy 2.07, whole-genome doublings 0.
